Somatic mutation profile of tumor specimen TCGA-C4-A0F7-01A (aliquot TCGA-C4-A0F7-01A-11D-A10S-08) from TCGA case TCGA-C4-A0F7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 77.8 years (28,428 days).
Specimen TCGA-C4-A0F7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c7ba16b-c70f-4b2a-beda-9fa3f73f2868.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C4-A0F7-10A (Blood Derived Normal), aliquot TCGA-C4-A0F7-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f24461bb-746e-4b0f-8967-d6321770de32

The open-access MAF lists 85 somatic variants for this specimen: 61 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1, RNA 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 70/78 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.514del p.I172Ffs*23 | Frame Shift Del (DEL) | VAF 84/431 reads (19%) | catalogued as COSV62930977; called by pindel, varscan2*
- ACHE | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV53816884; called by muse, mutect2, varscan2
- ANO8 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV50183477; called by muse, mutect2, varscan2
- ATP2A1 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 56/868 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV62869914; called by muse, mutect2
- ATXN7 | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs758328066, COSV55750389; called by muse, mutect2, varscan2
- BOP1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100265937, COSV56639676; called by muse, mutect2, varscan2
- CD200 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 30/166 reads (18%) | PolyPhen benign (0.192); catalogued as COSV59863633; called by muse, mutect2, varscan2
- CDKL4 | c.645_648del p.R215Sfs*2 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as COSV66510147; called by mutect2, pindel
- CSMD2 | c.6036C>G p.N2012K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53925298; called by muse, mutect2, varscan2
- CUL9 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs756258868, COSV52730396, COSV52733927; called by muse, mutect2, varscan2
- DDHD2 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs753948540, COSV68158176; called by muse, mutect2, varscan2
- DNAH11 | c.9620C>G p.A3207G | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60943084, COSV60962685; called by muse, mutect2
- DNM3 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62460846; called by muse, mutect2, varscan2
- EIF4A2 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 95/325 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); catalogued as rs779490566, COSV60625465; called by muse, mutect2, varscan2
- FLG | c.8316C>A p.D2772E | Missense Mutation (SNP) | VAF 372/1638 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV64243462; called by muse, mutect2, varscan2
- FLNA | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 77/97 reads (79%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as rs1409855324, COSV61045842; called by muse, mutect2, varscan2
- FRAS1 | c.9610C>T p.P3204S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV53621346; called by muse, mutect2, varscan2
- GLIS1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs747936449, COSV56547943; called by muse, mutect2, varscan2
- HRH1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs181783018, COSV67955609; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 94/312 reads (30%) | catalogued as rs765906022, COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- HSP90B1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55356236; called by muse, mutect2, varscan2
- IFNGR2 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51639706; called by muse, mutect2, varscan2
- IKZF2 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.248); catalogued as COSV59580189; called by muse, mutect2, varscan2
- KIF13A | c.4123A>G p.K1375E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV52455544; called by muse, mutect2, varscan2
- KIF13B | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV72879504; called by muse, mutect2, varscan2
- KIF21B | c.1768-2A>G p.X590_splice | Splice Site (SNP) | VAF 114/157 reads (73%) | catalogued as COSV59760147; called by muse, mutect2, varscan2
- KLK5 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369412139; called by muse, mutect2, varscan2
- MARVELD2 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs768081415, COSV57781180, COSV57781562; called by muse, mutect2, varscan2
- ME1 | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV63840246; called by muse, mutect2, varscan2
- ORAI2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs372227034; called by muse, mutect2, varscan2
- PHRF1 | c.1841G>A p.R614Q (on ENST00000264555 / NM_001286581.2; = p.R613Q on NM_020901.4) | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752856198, COSV52754578; called by muse, mutect2, varscan2
- PPP2R1B | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59536128; called by muse, mutect2
- PPP6R1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV69799992; called by muse, mutect2, varscan2
- PRDM2 | c.2996C>A p.S999Y | Missense Mutation (SNP) | VAF 103/176 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs1282388017, COSV52449590; called by muse, mutect2, varscan2
- RCBTB1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs370652161; called by muse, mutect2, varscan2
- RGS12 | c.3187G>A p.V1063M | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774892640, COSV58753707; called by muse, mutect2, varscan2
- RIMS3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.794); catalogued as rs1298145111, COSV65504845; called by muse, mutect2, varscan2
- RXRG | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs901274500, COSV63232407; called by muse, mutect2, varscan2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SETBP1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 74/105 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV56326768, COSV56335904; called by muse, mutect2, varscan2
- SETX | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56388083; called by muse, mutect2, varscan2
- SI | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769799372, COSV52285106, COSV52289398; called by muse, mutect2, varscan2
- SLC39A1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs780510822, COSV57843739; called by muse, mutect2, varscan2
- SOGA1 | c.1928G>T p.R643L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs774245629, COSV52925874; called by muse, mutect2, varscan2
- SULT2B1 | c.47A>T p.Y16F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52376898; called by muse, mutect2, varscan2
- SWSAP1 | c.189G>A p.K63= (on ENST00000312423; = p.K84= on NM_175871.4) | Splice Region (SNP) | VAF 120/482 reads (25%) | catalogued as COSV55800760; called by muse, mutect2, varscan2
- TAB2 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs760538795, COSV53850887; called by muse, mutect2, varscan2
- TEX55 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1392136568, COSV55211539; called by muse, mutect2, varscan2
- TGFBR3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs957231039, COSV53027400; called by muse, mutect2, varscan2
- TNR | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs769669262, COSV54894031; called by muse, mutect2
- UBR4 | c.7461A>T p.E2487D | Missense Mutation (SNP) | VAF 150/282 reads (53%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.899); catalogued as COSV64392311; called by muse, mutect2, varscan2
- UGT8 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs77695673, COSV60418760; called by muse, mutect2, varscan2
- ZNF567 | c.1216G>T p.A406S (on ENST00000536254 / NM_001322913.1; = p.A375S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62445804; called by muse, mutect2, varscan2
- ZNF658 | c.752dup p.N251Kfs*3 | Frame Shift Ins (INS) | VAF 42/86 reads (49%) | catalogued as rs964837363; called by mutect2, pindel, varscan2
- ZNF98 | c.587A>T p.H196L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1237676474; called by muse, mutect2, varscan2
- AK9 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- KMT2D | c.13268del p.P4423Hfs*9 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- KMT2D | c.6768_6772del p.V2257* | Frame Shift Del (DEL) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- TAF5 | c.722dup p.Y241* | Nonsense Mutation (INS) | VAF 102/288 reads (35%) | called by mutect2, pindel, varscan2
- TP53I13 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 64/77 reads (83%) | called by muse, mutect2, varscan2
- A2ML1 | c.2610T>A p.I870= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV55292917; called by muse, varscan2
- ANKRD49 | c.666T>C p.Y222= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV57060302; called by muse, mutect2, varscan2
- CBLL2 | c.849G>A p.A283= | Silent (SNP) | VAF 73/94 reads (78%) | catalogued as COSV60368664; called by muse, mutect2, varscan2
- CTNNA2 | c.279A>T p.V93= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV63578283; called by muse, mutect2, varscan2
- DNAH7 | c.1275C>T p.I425= | Silent (SNP) | VAF 166/326 reads (51%) | catalogued as COSV56771111; called by muse, mutect2, varscan2
- FBXO24 | c.183C>G p.A61= (on ENST00000241071 / NM_033506.3; = p.A99= on NM_012172.5) | Silent (SNP) | VAF 66/99 reads (67%) | catalogued as COSV53827123; called by muse, mutect2, varscan2
- FOXK1 | c.858C>T p.A286= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs763169832, COSV61066740; called by muse, mutect2, varscan2
- HDGFL2 | c.1611G>A p.E537= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100012462, COSV56683480; called by muse, mutect2, varscan2
- HECW1 | c.1881G>A p.T627= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs773284429, COSV67832699; called by muse, mutect2, varscan2
- KCNB2 | c.366A>G p.E122= | Silent (SNP) | VAF 40/166 reads (24%) | catalogued as rs1470567680, COSV73051009; called by muse, mutect2, varscan2
- MYT1L | c.48G>A p.G16= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs377141211; called by muse, mutect2, varscan2
- PLCB3 | c.3690G>A p.E1230= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- PRKCD | c.147G>A p.P49= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs782493646, COSV57848627; called by muse, mutect2, varscan2
- PYGM | c.462C>T p.A154= | Silent (SNP) | VAF 153/205 reads (75%) | catalogued as rs1410374422, COSV51219829; called by muse, mutect2, varscan2
- RPGRIP1L | c.2652G>A p.L884= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV50909038; called by muse, mutect2, varscan2
- SLC19A1 | c.918C>T p.N306= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs745419707, COSV60755581; called by muse, varscan2
- SNW1 | c.1578C>T p.H526= | Silent (SNP) | VAF 109/315 reads (35%) | catalogued as rs753036600, COSV53174375; called by muse, mutect2, varscan2
- SRD5A1 | c.237C>T p.L79= | Silent (SNP) | VAF 19/226 reads (8%) | catalogued as rs1213132040, COSV52955230; called by muse, mutect2
- TECTA | c.5862G>C p.T1954= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs758886759, COSV50730465, COSV50786115; called by muse, mutect2, varscan2
- TRMT10A | c.343T>C p.L115= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV56745379; called by muse, mutect2
- TST | c.429C>T p.S143= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs755745420, COSV50765213; called by muse, mutect2, varscan2
- ZFHX4 | c.10461T>C p.V3487= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs371578848; called by muse, mutect2, varscan2
- ADGRE4P | n.1083G>T | RNA (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- Z82190.2 | c.1787-18101A>G | Intron (SNP) | VAF 140/537 reads (26%) | catalogued as COSV50735255; called by muse, mutect2, varscan2
